Gene-level copy-number profile of tumor specimen TCGA-49-4490-01A from TCGA case TCGA-49-4490, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 45.5 years (16,634 days).
Specimen TCGA-49-4490-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.07e0e04d-a578-4ff6-8972-8dd82b0b0c2e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-49-4490-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b04915be-c352-4873-86af-6e4de6143177

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 282; copy number 2: 1,028; copy number 3: 12,560; copy number 4: 11,312; copy number 5: 7,687; copy number 6: 16,001; copy number 7: 4,791; copy number 8: 686; copy number 9: 4,684; copy number 11: 673; copy number 12: 19; copy number 14: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-49-4490-01A-21D-1854-01): tumor purity 0.26, ploidy 5.15, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–26,796,304, 43 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 51 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:99,646,113–101,390,303, 51 genes, copy number 14: PALMD, HMGB3P10, FRRS1, RNU4-75P, Y_RNA, AC096949.1, AGL, AC118553.1, SLC35A3, AC118553.2, RNU6-750P, RNU6-1318P, MFSD14A, AC093019.2, SASS6, AC093019.1, TRMT13, LRRC39, DBT, RPL23AP90, BRI3P1, AL445928.2, AL445928.1, RTCA-AS1, RTCA, MIR553, AC104457.1, AC104457.2, CDC14A, BCAS2P2, AL589990.1, GPR88, AC099670.1, LINC01349, AC099670.3, AC099670.2, VCAM1, EXTL2, AC104506.1, SLC30A7, HNRNPA1P68, DPH5, AC093157.2, AC093157.1, AC093157.3, AC119501.1, AL109741.1, S1PR1, AL109741.2, PPIAP7, LINC01307.

Autosomal genes at a single copy (total copy number 1): 282. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
